MMRF case MMRF_2368 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2c3ee8e8-0819-47c1-b26f-3d30be31e17f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.0 years (30,330 days); ISS stage: III; Days to last known disease status: 133 days; Days to last follow up: 133 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 5.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.1 mg/dL; Immunoglobulin G 59.4 g/L; Immunoglobulin A 0.067 g/L; Immunoglobulin M 0.111 g/L; Beta 2 Microglobulin 14.1 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 4.03 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.5 mmol/L; Calcium 2.28 mmol/L; Albumin 25 g/L; Total Protein 9.8 g/dL; Glucose 6.71 mmol/L; C-Reactive Protein 1.49 mg/dL.
- Day 72 (ECOG 1): Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 2.56 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 56.6 µmol/L; Calcium 2.13 mmol/L; Total Protein 5.7 g/dL; Glucose 5.01 mmol/L.
- Day 133 (ECOG 2): M Protein 1.6 g/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 0.133 g/L; Immunoglobulin M 0.128 g/L; Lactate Dehydrogenase 5.57 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.13 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 51.3 µmol/L; Calcium 2.18 mmol/L; Total Protein 5.7 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -17: Weight: 54 kg; Height: 149 cm.

Biospecimens (2 samples)
- Sample MMRF_2368_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2368_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
